Somatic mutation profile of tumor specimen TCGA-A4-A7UZ-01A (aliquot TCGA-A4-A7UZ-01A-12D-A34Z-10) from TCGA case TCGA-A4-A7UZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.9 years (26,264 days).
Specimen TCGA-A4-A7UZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5491040c-5761-42ac-b5ca-3a7c7702a195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A7UZ-10A (Blood Derived Normal), aliquot TCGA-A4-A7UZ-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/134486f5-0272-483d-b65a-58f1d0ee6f55

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 36, Silent 16, Frame Shift Del 9, Frame Shift Ins 5, Splice Site 2, In Frame Del 2, Translation Start Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.3983G>A p.R1328Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370672850; called by muse, mutect2, varscan2
- ADAM18 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 83/365 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99695719; called by muse, mutect2, varscan2
- ANO4 | c.2624T>G p.L875R (on ENST00000392977 / NM_001286615.2; = p.L840R on NM_178826.4) | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100153084; called by muse, mutect2, varscan2
- ARHGEF4 | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs753634743, COSV100388295; called by muse, mutect2, varscan2
- ATP9B | c.1163T>G p.L388* | Nonsense Mutation (SNP) | VAF 118/514 reads (23%) | catalogued as COSV100303726; called by muse, mutect2, varscan2
- BFAR | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99902297; called by muse, mutect2, varscan2
- CENPE | c.5212G>C p.D1738H | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV54390146; called by muse, mutect2, varscan2
- CPLX4 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV100231424; called by muse, mutect2
- CPXM1 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101013762; called by muse, mutect2
- CRHR2 | c.544-1G>A p.X182_splice | Splice Site (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100530060; called by muse, mutect2, varscan2
- DIDO1 | c.3822A>T p.K1274N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99826202; called by muse, mutect2, varscan2
- DNAH1 | c.5116A>G p.M1706V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1303254929, COSV101326175; called by muse, mutect2, varscan2
- EIF4A2 | c.973_974insA p.R325Qfs*7 | Frame Shift Ins (INS) | VAF 25/186 reads (13%) | catalogued as COSV99961251; called by mutect2, pindel, varscan2
- GJB7 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs768828808, COSV99738423; called by muse, mutect2, varscan2
- HEPHL1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100244053; called by muse, mutect2, varscan2
- IFNA2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV101206986; called by muse, mutect2, varscan2
- INTS14 | c.406C>G p.R136G (on ENST00000313182 / NM_001366360.2; = p.R57G on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV100499982; called by muse, mutect2, varscan2
- IRS1 | c.1764A>T p.E588D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100524651; called by muse, mutect2, varscan2
- ITFG1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141409020; called by muse, varscan2
- ITGAL | c.3275T>G p.L1092R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100776282; called by muse, varscan2
- KAZALD1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930600; called by muse, mutect2, varscan2
- KLHL34 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV101069947; called by muse, mutect2, varscan2
- LIMA1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100372548; called by muse, mutect2, varscan2
- LVRN | c.2447A>C p.N816T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100773524; called by muse, mutect2, varscan2
- MLH1 | c.2142G>T p.W714C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM960977, COSV51618068, COSV99212504; called by muse, mutect2, varscan2
- OR2J2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs371365216; called by muse, mutect2, varscan2
- PCNX1 | c.6299T>C p.L2100P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as COSV99455997; called by muse, mutect2, varscan2
- POLR2A | c.5677_5679del p.P1893del | In Frame Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs745782731; called by mutect2, pindel, varscan2
- PPRC1 | c.1743A>T p.Q581H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV99531761; called by muse, mutect2, varscan2
- PRDX5 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs368539290; called by muse, mutect2, varscan2
- RASGRF1 | c.3647C>G p.S1216C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101174568; called by muse, mutect2, varscan2
- RBBP8NL | c.1489G>C p.G497R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV99436719; called by muse, mutect2, varscan2
- RBX1 | c.315G>A p.K105= | Splice Region (SNP) | VAF 42/156 reads (27%) | catalogued as COSV99345425; called by muse, mutect2, varscan2
- RC3H2 | c.3393A>C p.K1131N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100605717; called by muse, mutect2, varscan2
- TELO2 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV99248464; called by muse, mutect2, varscan2
- TRERF1 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs200270446, COSV61668315; called by muse, mutect2, varscan2
- ZNF287 | c.1571_1573del p.L524del | In Frame Del (DEL) | VAF 28/220 reads (13%) | catalogued as rs768193322; called by pindel, varscan2
- ZW10 | c.644A>T p.K215I | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99562726; called by muse, varscan2
- ACACA | c.1201G>C p.A401P | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ALDOB | c.761dup p.T255Nfs*23 | Frame Shift Ins (INS) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- ATXN2 | c.1926del p.I643Yfs*5 (on ENST00000550104; = p.I483Yfs*5 on NM_002973.4) | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | called by mutect2, pindel, varscan2
- BRD8 | c.785_787+2del p.X262_splice (on ENST00000254900 / NM_139199.2; = p.X335_splice on NM_006696.4) | Splice Site (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- DHX8 | c.1784_1785del p.T595Nfs*54 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1186_1201del p.Q396Efs*100 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel
- GTF3C1 | c.104dup p.L37Afs*25 | Frame Shift Ins (INS) | VAF 55/143 reads (38%) | called by mutect2, pindel, varscan2
- IL18 | c.302_303del p.S101Cfs*4 | Frame Shift Del (DEL) | VAF 35/146 reads (24%) | called by pindel, varscan2
- KLHL15 | c.654_676delinsG p.I218Mfs*2 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by pindel, varscan2*
- LIMA1 | c.1712del p.V571Afs*3 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | called by mutect2, pindel, varscan2
- NLRP1 | c.3762_3772del p.S1255Hfs*7 (on ENST00000572272 / NM_033004.4; = p.S1255Hfs*40 on NM_014922.5) | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- PCDHB6 | c.2125G>T p.V709L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- PCDHB6 | c.2126T>C p.V709A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2
- PIK3C2B | c.1252_1255del p.N418Wfs*8 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- POLM | c.3_6dup p.P3Afs*13 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- RNLS | c.548dup p.Q184Afs*18 | Frame Shift Ins (INS) | VAF 6/65 reads (9%) | called by mutect2, pindel, varscan2
- SLC7A6OS | c.-3_8del | Translation Start Site (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- SUCLA2 | c.1169del p.K390Rfs*23 (on ENST00000643023; = p.K369Rfs*23 on NM_003850.3) | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, varscan2
- SYNRG | c.341A>C p.D114A | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AK8 | c.1083G>A p.Q361= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as rs1399964299, COSV100050156; called by muse, mutect2, varscan2
- C14orf28 | c.462C>T p.Y154= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs148597765; called by muse, mutect2, varscan2
- CAPN11 | c.2199G>A p.L733= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1174573293, COSV101291898; called by muse, mutect2, varscan2
- CFHR5 | c.225A>G p.E75= | Silent (SNP) | VAF 50/199 reads (25%) | catalogued as COSV99889049; called by muse, mutect2, varscan2
- DGAT2L6 | c.342T>C p.F114= | Silent (SNP) | VAF 74/150 reads (49%) | catalogued as COSV100284032; called by muse, mutect2, varscan2
- LNPEP | c.213G>A p.E71= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99183547; called by muse, mutect2, varscan2
- MOV10 | c.1233C>T p.I411= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100659627; called by muse, mutect2, varscan2
- MUC17 | c.12549T>C p.T4183= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV100073838; called by muse, mutect2
- RBFOX1 | c.852G>A p.R284= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100301960; called by mutect2, varscan2
- RBL2 | c.2328C>T p.S776= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100043774; called by muse, mutect2, varscan2
- SH2D1B | c.150C>T p.V50= | Silent (SNP) | VAF 46/212 reads (22%) | catalogued as COSV100854772, COSV100854835; called by muse, varscan2
- SYCP1 | c.2205T>C p.Y735= | Silent (SNP) | VAF 91/343 reads (27%) | catalogued as COSV101050993; called by muse, mutect2, varscan2
- SYPL1 | c.108C>T p.I36= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99070756, COSV99163455; called by muse, varscan2
- SYVN1 | c.1437G>A p.A479= (on ENST00000377190 / NM_172230.3; = p.A478= on NM_032431.3) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1429318060, COSV99589145; called by muse, mutect2, varscan2
- TELO2 | c.1233G>A p.E411= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV99248463; called by muse, mutect2, varscan2
- UTP14A | c.1395G>A p.Q465= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV100928976; called by muse, mutect2, varscan2
